Somatic mutation profile of tumor specimen TCGA-EY-A1H0-01A (aliquot TCGA-EY-A1H0-01A-11D-A13L-09) from TCGA case TCGA-EY-A1H0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G2; Age at diagnosis: 57.3 years (20,937 days).
Specimen TCGA-EY-A1H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7262eba4-8d04-4e99-b350-e2651e220067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EY-A1H0-10A (Blood Derived Normal), aliquot TCGA-EY-A1H0-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68e412bb-a925-48d3-bea8-cc8da39c38df

The open-access MAF lists 410 somatic variants for this specimen: 322 protein-altering or splice-affecting, 80 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Frame Shift Del 103, Silent 80, Nonsense Mutation 16, Frame Shift Ins 10, Splice Region 5, In Frame Del 5, Intron 4, Splice Site 4, 3'Flank 2, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 21/31 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NFE2L2 | c.246A>T p.E82D | Missense Mutation (SNP) | VAF 60/147 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 24/40 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PEX1 | c.1108del p.I370Lfs*17 | Frame Shift Del (DEL) | VAF 48/89 reads (54%) | catalogued as rs61750406; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.741dup p.P248Tfs*5 | Frame Shift Ins (INS) | VAF 72/103 reads (70%) | catalogued as rs587782341, CI043805, COSV64288762; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AASDHPPT | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs769999593, COSV53788350; called by muse, mutect2, varscan2
- AC013489.1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs778994249, COSV51553273; called by muse, mutect2, varscan2
- ACADS | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656877; called by muse, mutect2, varscan2
- ACBD7 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200704311, COSV62252241; called by muse, mutect2, varscan2
- ACP4 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54516763, COSV99567899; called by muse, mutect2, varscan2
- ADAMTS4 | c.581G>A p.C194Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as COSV100917596; called by muse, mutect2, varscan2
- ADAMTS7 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs143462516, COSV101183007; called by muse, mutect2, varscan2
- AHNAK | c.16613C>T p.A5538V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.711); catalogued as COSV99950004; called by muse, mutect2, varscan2
- AHNAK | c.13918G>C p.D4640H | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777308894, COSV99950006; called by muse, mutect2, varscan2
- AKAP1 | c.1977C>T p.G659= | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as rs769844139, COSV100028291; called by muse, mutect2, varscan2
- ALG10 | c.438del p.F146Lfs*20 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | catalogued as rs1163730964; called by mutect2, pindel, varscan2
- ALKBH7 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199888358, COSV99831812; called by muse, mutect2, varscan2
- ANGEL2 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854007; called by muse, mutect2, varscan2
- ANK3 | c.76del p.R26Gfs*21 | Frame Shift Del (DEL) | VAF 25/93 reads (27%) | catalogued as rs1373792937; called by mutect2, pindel, varscan2
- ANKIB1 | c.3217A>G p.S1073G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV99730064; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs759218332; called by mutect2, varscan2
- AOC1 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.476); catalogued as COSV100711034; called by muse, mutect2, varscan2
- AQP9 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV99583288; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ASPHD2 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs781486947, COSV53218658; called by muse, mutect2, varscan2
- ATE1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as rs755046399, COSV99817878; called by muse, mutect2, varscan2
- ATL1 | c.1111del p.M371Wfs*29 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | catalogued as rs1566733927; called by mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP2B3 | c.3524del p.P1175Rfs*12 | Frame Shift Del (DEL) | VAF 11/29 reads (38%) | catalogued as rs782513834; called by mutect2, pindel, varscan2
- ATP5F1B | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.161); catalogued as COSV99468017; called by muse, mutect2, varscan2
- ATP5MD | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100428332; called by muse, mutect2, varscan2
- ATP6V1H | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV100778886; called by muse, mutect2, varscan2
- ATXN7L2 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs767873540, COSV63992469; called by muse, mutect2, varscan2
- ATXN7L3 | c.703C>T p.R235* (on ENST00000389384 / NM_001382309.1; = p.R242* on NM_001382308.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV60228497; called by muse, mutect2, varscan2
- BAX | c.265del p.R89Efs*44 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as COSV53170202; called by mutect2, pindel, varscan2
- BCL9 | c.2459T>A p.L820Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99325991; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs755506199; called by mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 38/49 reads (78%) | catalogued as rs763134487; called by mutect2, varscan2
- BTBD17 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs189934812, COSV100945388; called by muse, mutect2, varscan2
- C10orf90 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1333506506, COSV52950556; called by muse, mutect2, varscan2
- C12orf40 | c.18del p.S7Pfs*6 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV61129099; called by mutect2, pindel, varscan2
- C12orf60 | c.605del p.N202Ifs*21 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as COSV99967032; called by mutect2, pindel, varscan2
- CACNA1C | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV100223022; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC60 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.709); catalogued as COSV100555832; called by muse, mutect2, varscan2
- CDH8 | c.2278A>G p.S760G | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1186732457, COSV100184452; called by muse, mutect2, varscan2
- CEMIP2 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.456); catalogued as COSV100987535; called by muse, varscan2
- CFAP46 | c.7160del p.K2387Rfs*4 | Frame Shift Del (DEL) | VAF 71/239 reads (30%) | catalogued as rs775889105; called by mutect2, pindel, varscan2
- CHD3 | c.4325G>T p.R1442L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100390966, COSV100391815; called by muse, mutect2, varscan2
- CHKB | c.1008_1010del p.E336del | In Frame Del (DEL) | VAF 5/48 reads (10%) | catalogued as rs778645316; called by pindel, varscan2
- CHRM4 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.067); catalogued as rs1159673748, COSV63126404; called by muse, mutect2, varscan2
- CIC | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV99360405; called by muse, mutect2, varscan2
- CLCN2 | c.1142del p.P381Lfs*35 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs1217596296; called by mutect2, pindel, varscan2
- CLPP | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1400412385, COSV99832082; called by muse, mutect2, varscan2
- CLSTN3 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56934739, COSV99867818; called by muse, mutect2, varscan2
- CRISP3 | c.764C>A p.T255N (on ENST00000371159 / NM_001368123.1; = p.T237N on NM_006061.4) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1462903848, COSV99539369; called by muse, mutect2
- CROT | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV99711443; called by muse, mutect2, varscan2
- CSRNP2 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99950549; called by muse, mutect2
- CTTN | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100098479; called by muse, mutect2, varscan2
- CXCL16 | c.584dup p.N195Kfs*57 | Frame Shift Ins (INS) | VAF 20/56 reads (36%) | catalogued as rs1439291126; called by mutect2, varscan2
- CXCL2 | c.308del p.N103Mfs*50 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | catalogued as rs745343380; called by mutect2, pindel, varscan2
- DAZAP1 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.042); catalogued as rs780195006, COSV99245541; called by muse, mutect2, varscan2
- DEDD2 | c.655T>C p.S219P | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100260390; called by muse, mutect2, varscan2
- DEFB4A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV100156658; called by muse, mutect2, varscan2
- DGKK | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101053247; called by muse, mutect2, varscan2
- DKKL1 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); catalogued as rs1315428412, COSV99678562; called by muse, mutect2, varscan2
- DMD | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV99926975; called by muse, mutect2, varscan2
- DNAH17 | c.4297C>T p.R1433W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1213084019, COSV67753730; called by muse, mutect2, varscan2
- DOCK1 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs746815750, COSV99733313; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs1239294263; called by mutect2, pindel, varscan2
- DRP2 | c.1885T>A p.F629I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100872086; called by muse, mutect2, varscan2
- DYRK1B | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546776; called by muse, mutect2, varscan2
- EDEM3 | c.1974del p.F658Lfs*4 | Frame Shift Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs1173052284; called by mutect2, pindel, varscan2
- EGLN2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100393872; called by muse, mutect2, varscan2
- EIF3CL | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV101086025; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764631776, COSV100349445; called by muse, mutect2, varscan2
- ELF1 | c.1247A>G p.Q416R | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.39); catalogued as COSV99523383; called by muse, mutect2, varscan2
- ELL | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53214488; called by muse, mutect2, varscan2
- ENPP4 | c.628del p.I210* | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs756006851; called by mutect2, pindel, varscan2
- ENTPD4 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 10/176 reads (6%) | catalogued as rs1012994702, COSV100652826; called by muse, mutect2
- FAM124A | c.584G>A p.R195Q (on ENST00000322475 / NM_001242312.2; = p.R231Q on NM_145019.4) | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs763889748, COSV99696485; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAT3 | c.2939A>G p.N980S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as COSV99971889; called by muse, mutect2, varscan2
- FBXL19 | c.1720del p.V574Wfs*11 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as COSV57942522; called by mutect2, pindel, varscan2
- FCER1G | c.51G>A p.A17= | Splice Region (SNP) | VAF 11/70 reads (16%) | catalogued as rs546630081, COSV99248498; called by muse, mutect2, varscan2
- FCGBP | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs766227115; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | catalogued as rs768979093, COSV55110370; called by mutect2, varscan2
- FFAR2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs568119991, COSV55833001; called by muse, mutect2, varscan2
- FLNA | c.6380G>A p.G2127D (on ENST00000369850 / NM_001110556.2; = p.G2119D on NM_001456.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100775341; called by muse, mutect2, varscan2
- FLRT3 | c.1721A>T p.D574V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99445243; called by muse, mutect2, varscan2
- FLT3 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99610429; called by muse, mutect2
- FREM1 | c.4580del p.P1527Lfs*6 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as COSV66531453; called by mutect2, pindel, varscan2
- FRMPD4 | c.99G>T p.Q33H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101044257; called by mutect2, varscan2
- FZD10 | c.1187G>A p.G396D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs891296853, COSV99969653; called by muse, mutect2, varscan2
- GADD45GIP1 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755977311, COSV100380524; called by muse, mutect2, varscan2
- GLG1 | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 65/140 reads (46%) | catalogued as COSV99216380; called by muse, mutect2, varscan2
- GLMN | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.622); catalogued as COSV100950221; called by muse, mutect2, varscan2
- GLRA4 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.477); catalogued as rs777996283, COSV60327413, COSV60327781; called by muse, mutect2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAT3 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101242423; called by muse, mutect2, varscan2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs763679060; called by mutect2, varscan2
- GRM3 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100862974; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 31/80 reads (39%) | catalogued as rs754199513; called by mutect2, varscan2
- GSTCD | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100853884; called by muse, mutect2, varscan2
- HAND2 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV100854260; called by muse, mutect2, varscan2
- HDGFL1 | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs753700254, COSV100014752; called by muse, mutect2, varscan2
- HERC1 | c.11980G>T p.G3994* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV101497041; called by muse, mutect2, varscan2
- HID1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs750214001, COSV100585963, COSV100586117; called by muse, mutect2, varscan2
- HIVEP2 | c.6713A>G p.H2238R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV50128535; called by muse, mutect2, varscan2
- HLA-A | c.426C>A p.Y142* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs41553319, CM098995, CM1412097, COSV100954719, COSV65137020; called by muse, mutect2, varscan2
- HP | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs373168016, COSV100577618; called by muse, varscan2
- HSD17B14 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1257748441, COSV99613420; called by muse, mutect2, varscan2
- IGSF22 | c.2159C>T p.T720M (on ENST00000319338; = p.T821M on NM_173588.4) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777008340, COSV100080561; called by muse, mutect2, varscan2
- IL2RB | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs141522549; called by muse, mutect2, varscan2
- INTS4 | c.2720G>A p.C907Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100490173; called by muse, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 50/105 reads (48%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ITPRID2 | c.3109C>T p.R1037C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as rs771813501, COSV100238821; called by muse, mutect2
- KARS1 | c.299A>T p.H100L | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.095); catalogued as rs1298749484, COSV100094614; called by muse, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | catalogued as rs1229306184; called by mutect2, pindel, varscan2
- KCNJ15 | c.986A>G p.Q329R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as COSV100154444; called by muse, mutect2
- KCNJ3 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716592; called by muse, mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 44/142 reads (31%) | catalogued as rs753256170; called by mutect2, pindel, varscan2
- KCTD9 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs768624898, COSV99648882; called by muse, mutect2, varscan2
- KDM2B | c.3613C>T p.Q1205* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100997693; called by muse, mutect2, varscan2
- KDM3A | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV100461082; called by muse, mutect2, varscan2
- KIF1C | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100297324; called by muse, mutect2, varscan2
- KIF26A | c.792dup p.V265Rfs*5 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | catalogued as rs1489615146; called by mutect2, varscan2
- KIFC2 | c.1196G>A p.C399Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV100024028; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KRT6B | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754808789, COSV52884532; called by muse, mutect2, varscan2
- LCTL | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768069134, COSV100328379; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRP5 | c.4025G>A p.R1342Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.882); catalogued as rs150088620, CM129426, COSV99592745; called by muse, mutect2, varscan2
- LRRC14 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs776222160, COSV52880015; called by muse, mutect2, varscan2
- LRRC27 | c.1548del p.F516Lfs*22 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as rs761680254; called by mutect2, pindel, varscan2
- LRRFIP1 | c.640G>A p.E214K (on ENST00000392000 / NM_001137552.2; = p.E190K on NM_004735.4) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs760008859, COSV55248913; called by muse, mutect2, varscan2
- LSAMP | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs1409878321, COSV100373078; called by muse, mutect2, varscan2
- MAP4K2 | c.1621C>A p.L541M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.183); catalogued as COSV99581267; called by muse, mutect2, varscan2
- MAST4 | c.2959C>T p.Q987* (on ENST00000403625 / NM_001164664.2; = p.Q798* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99846222; called by muse, mutect2, varscan2
- MED16 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766224197, COSV99516392; called by muse, mutect2, varscan2
- MED25 | c.602del p.P201Rfs*13 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | catalogued as rs748546983; ClinVar: uncertain significance; called by mutect2, varscan2
- MEGF10 | c.2248T>A p.F750I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.365); catalogued as COSV57259370; called by muse, mutect2, varscan2
- MEX3D | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101183559; called by muse, mutect2, varscan2
- MFN2 | c.1841C>A p.T614N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); catalogued as COSV99337149; called by muse, mutect2, varscan2
- MN1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.078); catalogued as COSV100180204; called by muse, mutect2, varscan2
- MPI | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.041); catalogued as rs766010024, COSV60396624; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs759847587; called by mutect2, varscan2
- MUC13 | c.231T>G p.H77Q | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV100222524; called by muse, mutect2, varscan2
- MUC16 | c.8468C>T p.P2823L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV101202015; called by muse, mutect2, varscan2
- MUC16 | c.6159G>A p.W2053* | Nonsense Mutation (SNP) | VAF 31/56 reads (55%) | catalogued as COSV101202016; called by muse, mutect2, varscan2
- MYBPC3 | c.3134T>C p.V1045A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99921059; called by muse, mutect2, varscan2
- MYO15A | c.9731C>T p.A3244V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99234721; called by muse, mutect2, varscan2
- MYO3A | c.1486A>T p.T496S | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99778779, COSV99781893; called by muse, mutect2, varscan2
- NAT9 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs148689395; called by muse, mutect2, varscan2
- NAV2 | c.3283G>A p.A1095T (on ENST00000396087 / NM_001244963.2; = p.A1072T on NM_145117.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs751815417, COSV60656569; called by muse, mutect2, varscan2
- NELL1 | c.2354G>T p.G785V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV100122390; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | catalogued as rs752284115; called by mutect2, varscan2
- NFKB2 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.557); catalogued as rs201099063, COSV99194154; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHLRC2 | c.1769C>T p.T590I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100993038; called by muse, mutect2, varscan2
- NINL | c.2714G>T p.R905M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99626533; called by muse, mutect2, varscan2
- NLRP8 | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.082); catalogued as COSV99406091; called by mutect2, varscan2
- NPEPL1 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs560635798, COSV100622611; called by muse, varscan2
- NRK | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99689364; called by mutect2, varscan2
- NRN1L | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1044247559, COSV59302081; called by muse, mutect2, varscan2
- NT5DC3 | c.914T>G p.F305C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101231053; called by muse, mutect2, varscan2
- NUDT13 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100624875; called by muse, mutect2
- OR56A3 | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100290394; called by muse, mutect2, varscan2
- PACC1 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99801729; called by muse, mutect2, varscan2
- PCDH11X | c.3366A>C p.K1122N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.159); catalogued as COSV100015869; called by muse, mutect2, varscan2
- PCDHB10 | c.1975C>T p.H659Y | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV99505141; called by muse, mutect2, varscan2
- PCDHB3 | c.2171G>A p.R724H | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV99166913; called by muse, mutect2, varscan2
- PCID2 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.315); catalogued as COSV99872716; called by muse, mutect2, varscan2
- PCNX4 | c.3235T>C p.Y1079H (on ENST00000406854 / NM_001330177.2; = p.Y845H on NM_022495.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.161); catalogued as rs1566519325, COSV100470929; called by muse, mutect2, varscan2
- PDCD11 | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874433; called by muse, mutect2, varscan2
- PDCD11 | c.4504G>A p.V1502M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1195777349, COSV100874434; called by muse, mutect2, varscan2
- PDE3A | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); catalogued as COSV100762895; called by muse, mutect2, varscan2
- PHF20L1 | c.259T>A p.F87I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99622286; called by muse, mutect2, varscan2
- PHF23 | c.726del p.S243Vfs*24 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as COSV50036587; called by mutect2, pindel, varscan2
- PIK3AP1 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767463653, COSV59537997; called by muse, mutect2, varscan2
- PIK3CA | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99844728; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563del p.G2188Efs*28 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | catalogued as rs772426616; called by mutect2, pindel, varscan2
- PLD4 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV66915158; called by muse, mutect2, varscan2
- PLXNB2 | c.3625A>G p.M1209V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.287); catalogued as COSV100834344; called by muse, mutect2, varscan2
- PNLIPRP1 | c.591A>C p.E197D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as COSV100724569; called by muse, mutect2, varscan2
- PNPLA6 | c.1974G>A p.R658= (on ENST00000414982 / NM_001166111.2; = p.R610= on NM_006702.5) | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs1482457640, COSV55379510; called by muse, mutect2, varscan2
- PRDM16 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs748390268, COSV99579270; called by muse, mutect2, varscan2
- PRDX2 | c.271del p.R91Gfs*9 | Frame Shift Del (DEL) | VAF 16/35 reads (46%) | catalogued as rs752658197, COSV56878950; called by mutect2, pindel, varscan2
- PRKG2 | c.2193G>T p.E731D | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100020672; called by muse, mutect2
- PROX2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs774572009, COSV101507832; called by muse, mutect2, varscan2
- PRPF19 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs1354313581, COSV99920817; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs753236928; called by mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 45/103 reads (44%) | catalogued as rs778292578; called by mutect2, varscan2
- PUS3 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1366134990, COSV99917120; called by muse, mutect2, varscan2
- PVRIG | c.236del p.G79Afs*245 | Frame Shift Del (DEL) | VAF 52/145 reads (36%) | catalogued as rs768997455; called by mutect2, pindel, varscan2
- RAPGEF4 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs368215776; called by muse, mutect2, varscan2
- RASAL1 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99922188; called by muse, mutect2, varscan2
- RCOR1 | c.528T>A p.H176Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99217842; called by muse, mutect2, varscan2
- REV3L | c.7877A>G p.Y2626C | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62622301; called by muse, varscan2
- RFC2 | c.535+1G>T p.X179_splice (on ENST00000055077 / NM_181471.3; = p.X145_splice on NM_002914.4) | Splice Site (SNP) | VAF 15/42 reads (36%) | catalogued as COSV99278159; called by muse, mutect2, varscan2
- RIMS1 | c.3979G>A p.D1327N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV99331080; called by muse, mutect2, varscan2
- RNASEH1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763190915, COSV59438093; called by muse, mutect2, varscan2
- RNF170 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as COSV99533922; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 35/65 reads (54%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNPEP | c.784_786del p.E262del | In Frame Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs765672429; called by pindel, varscan2
- RPS25 | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV100548948; called by muse, mutect2, varscan2
- RTL3 | c.389A>G p.H130R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100330166; called by muse, mutect2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs747510098; called by mutect2, varscan2
- RTP1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100398800; called by muse, mutect2, varscan2
- SAMSN1 | c.613G>T p.G205* | Nonsense Mutation (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99580777, COSV99582607; called by muse, mutect2
- SDR39U1 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99250178; called by muse, mutect2, varscan2
- SEC11C | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100231133; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SESN3 | c.526-2A>G p.X176_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99566094; called by muse, mutect2, varscan2
- SF3B1 | c.3776G>A p.R1259Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs771847036, COSV100136029; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | catalogued as rs747473028; called by mutect2, varscan2
- SIX5 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as rs781343581, COSV99353770; called by muse, mutect2, varscan2
- SLC12A3 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99344884; called by muse, mutect2, varscan2
- SLC13A5 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138841868; ClinVar: uncertain significance; called by muse, mutect2
- SLC1A7 | c.795G>A p.V265= | Splice Region (SNP) | VAF 17/44 reads (39%) | catalogued as COSV101020271; called by muse, mutect2, varscan2
- SLC34A2 | c.1310C>T p.T437M | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs749870943, COSV101158475; called by muse, mutect2, varscan2
- SLC5A7 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV50890104; called by muse, mutect2, varscan2
- SLC8A2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99370366; called by muse, mutect2, varscan2
- SLC8A3 | c.1024T>C p.Y342H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100776407; called by muse, mutect2, varscan2
- SOGA1 | c.2919G>T p.T973= | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as COSV52930377, COSV99415804; called by muse, mutect2, varscan2
- SPIDR | c.1133T>A p.V378D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99856259; called by muse, mutect2, varscan2
- SSBP3 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs529305364, COSV100486693; called by muse, mutect2, varscan2
- STAC3 | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs1023756156, COSV100234808, COSV60414697; called by muse, mutect2, varscan2
- SUPT5H | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.122); catalogued as COSV100782169; called by muse, mutect2, varscan2
- SYT15 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs781979888, COSV65432407; called by muse, mutect2, varscan2
- TAT | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs774749746, COSV63532262, COSV63533172; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs748021112; called by mutect2, varscan2
- TCP11 | c.601C>T p.R201W (on ENST00000512012; = p.R139W on NM_018679.5) | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs200541069, COSV55133777; called by muse, mutect2, varscan2
- TEX33 | c.287C>A p.A96E (on ENST00000381821 / NM_001163857.2; = p.A11E on NM_178552.4) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs201179656, COSV101111504, COSV67821182; called by muse, mutect2, varscan2
- TGS1 | c.1472A>G p.K491R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99485831; called by muse, mutect2, varscan2
- TIMM29 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99450381; called by muse, mutect2
- TLR10 | c.2256del p.A753Hfs*28 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs564674109; called by mutect2, varscan2
- TM4SF4 | c.36del p.T13Pfs*23 | Frame Shift Del (DEL) | VAF 26/63 reads (41%) | catalogued as rs747355584; called by mutect2, pindel, varscan2
- TMEM121 | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs781938902, COSV101180083; called by muse, mutect2, varscan2
- TMEM25 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs140899282; called by muse, mutect2
- TNN | c.1070C>T p.A357V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs1247133418, COSV99513247; called by muse, mutect2, varscan2
- TRAF2 | c.26del p.P9Lfs*77 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs748531430; called by mutect2, pindel, varscan2
- TRIM56 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV100047853; called by muse, mutect2
- TSHZ3 | c.1637dup p.Y547Lfs*35 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | catalogued as rs750388867; called by mutect2, varscan2
- TSKU | c.410A>C p.N137T | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV100290273; called by muse, mutect2, varscan2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | catalogued as rs756650873; called by mutect2, varscan2
- UBN2 | c.1346C>A p.P449Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99944577; called by muse, mutect2, varscan2
- UHRF2 | c.1673C>G p.A558G | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.198); catalogued as rs1346306495, COSV99437298; called by muse, mutect2, varscan2
- USP37 | c.488T>C p.L163P | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as COSV99294941; called by muse, mutect2, varscan2
- USP9X | c.82dup p.L28Pfs*10 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | catalogued as rs758083405; called by mutect2, varscan2
- UTP25 | c.1397_1399del p.K466del | In Frame Del (DEL) | VAF 12/62 reads (19%) | catalogued as rs763324038; called by pindel, varscan2
- VCAN | c.9317C>A p.P3106H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54119024; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 13/29 reads (45%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS4B | c.128A>G p.H43R | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.782); catalogued as COSV99447728; called by muse, mutect2, varscan2
- WASF2 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV101420829; called by muse, mutect2, varscan2
- ZBED1 | c.1628T>A p.V543D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as rs1456297196, COSV100586133; called by muse, mutect2, varscan2
- ZBTB41 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100963503; called by muse, mutect2, varscan2
- ZC3H3 | c.302del p.G101Afs*102 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | catalogued as rs760469533; called by pindel, varscan2
- ZFPM2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV68278055, COSV68292263; called by muse, mutect2, varscan2
- ZNF524 | c.214del p.V72* | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as rs1249713061; called by mutect2, pindel, varscan2
- ABLIM2 | c.1230del p.S411Pfs*17 (on ENST00000341937 / NM_001130084.2; = p.S444Pfs*17 on NM_001130083.2) | Frame Shift Del (DEL) | VAF 48/128 reads (38%) | called by mutect2, varscan2
- ANAPC1 | c.693del p.F231Lfs*10 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- ATAD5 | c.3579del p.F1193Lfs*6 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- AXIN2 | c.65dup p.R23Afs*118 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- CADPS | c.276del p.S93Afs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- CCSER2 | c.1159del p.M387* | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- CEMIP2 | c.579del p.K193Nfs*55 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by pindel, varscan2
- CORO2B | c.185del p.G62Afs*61 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- CTCF | c.610del p.T204Qfs*18 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- DAAM1 | c.2724+3_2724+6del p.X908_splice | Splice Site (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- DCAF1 | c.2126_2127del p.R709Kfs*7 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- DCLK1 | c.1412del p.G471Efs*25 | Frame Shift Del (DEL) | VAF 31/75 reads (41%) | called by mutect2, pindel, varscan2
- DDX17 | c.488del p.G163Efs*20 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- FAM91A1 | c.1995del p.A666Qfs*23 | Frame Shift Del (DEL) | VAF 43/91 reads (47%) | called by mutect2, pindel, varscan2
- FAM98A | c.399del p.A134Lfs*13 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- GALNS | c.1360del p.L454Sfs*41 | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- HOXB3 | c.1236_1237del p.H413Pfs*8 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by pindel, varscan2
- ICOS | c.285del p.L96Yfs*26 | Frame Shift Del (DEL) | VAF 30/72 reads (42%) | called by mutect2, pindel, varscan2
- IRS4 | c.605dup p.R203Afs*30 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- KCTD21 | c.33del p.K12Sfs*10 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- KIAA1328 | c.398_400del p.K133del | In Frame Del (DEL) | VAF 8/27 reads (30%) | called by pindel, varscan2
- KIF20B | c.3395del p.N1132Mfs*11 (on ENST00000371728 / NM_001284259.2; = p.N1092Mfs*11 on NM_016195.4) | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- LAMA2 | c.4640del p.T1547Sfs*48 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- MAP2K3 | c.862del p.Q288Sfs*19 (on ENST00000342679 / NM_145109.3; = p.Q259Sfs*19 on NM_002756.4) | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | called by mutect2, pindel, varscan2
- MAP9 | c.217del p.M73* | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- MCOLN1 | c.1644del p.T549Pfs*31 | Frame Shift Del (DEL) | VAF 39/102 reads (38%) | called by mutect2, pindel, varscan2
- NIPAL2 | c.974del p.L325Wfs*69 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- NYAP1 | c.1714del p.V572Cfs*2 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- OR6K6 | c.837del p.F279Lfs*9 (on ENST00000368144; = p.F255Lfs*9 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, varscan2
- PSIP1 | c.799del p.T267Qfs*37 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | called by mutect2, pindel, varscan2
- PTCH2 | c.2805_2810dup p.E936_A937dup | In Frame Ins (INS) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- RERE | c.4009del p.L1337Cfs*35 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | called by mutect2, pindel, varscan2
- RGL1 | c.1748del p.K583Sfs*25 (on ENST00000360851 / NM_001297672.2; = p.K618Sfs*25 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- RIMBP3 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- RND3 | c.347del p.K116Sfs*31 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- SATB2 | c.382del p.L128Sfs*4 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- SDHA | c.403del p.D135Tfs*8 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | called by mutect2, pindel, varscan2
- SIPA1L1 | c.4359del p.S1454Hfs*31 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- SLC12A8 | c.1803+1dup p.X601_splice | Splice Site (INS) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- SLC2A3 | c.158dup p.P54Tfs*3 | Frame Shift Ins (INS) | VAF 17/86 reads (20%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.1485del p.K495Nfs*2 | Frame Shift Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- SUSD4 | c.1059del p.R354Gfs*16 | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- TAF1L | c.1994del p.K665Rfs*4 | Frame Shift Del (DEL) | VAF 50/121 reads (41%) | called by mutect2, varscan2
- TET1 | c.3297del p.V1100Lfs*40 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- TLE1 | c.2220del p.S741Qfs*14 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel, varscan2
- TM6SF1 | c.1087del p.T363Qfs*21 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- TRIM17 | c.137del p.K46Rfs*35 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- TRIM26 | c.1321del p.V441Wfs*6 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- VCAM1 | c.170del p.F57Sfs*7 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- YIPF3 | c.225_227del p.E75del | In Frame Del (DEL) | VAF 14/34 reads (41%) | called by pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.3018del p.K1006Nfs*31 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | called by mutect2, varscan2
- ZNF484 | c.1129del p.I377Ffs*23 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- ZNF641 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- ZNF658 | c.1821_1822del p.C607* | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | called by pindel, varscan2
- ZNF878 | c.138del p.K46Nfs*18 | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | called by mutect2, pindel, varscan2
- ABCG1 | c.609G>A p.A203= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs201037860, COSV100494217; called by muse, mutect2, varscan2
- AMPD2 | c.1524C>T p.R508= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs201301109, COSV99858193; called by muse, mutect2, varscan2
- BAIAP3 | c.3105G>A p.A1035= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs772799963, COSV99136413; called by muse, mutect2, varscan2
- BICC1 | c.2445C>T p.N815= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs1308731263, COSV99570989; called by muse, mutect2, varscan2
- C11orf24 | c.549T>C p.T183= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV100422768; called by muse, mutect2, varscan2
- C11orf68 | c.642C>T p.Y214= (on ENST00000530188; = p.Y255= on NM_031450.4) | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV100437193; called by muse, mutect2, varscan2
- CACNA2D1 | c.87G>T p.S29= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100667558; called by muse, mutect2, varscan2
- CAPZA1 | c.237C>T p.H79= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs540925939, COSV99583502; called by muse, mutect2, varscan2
- CBFA2T2 | c.99G>A p.S33= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs779280088, COSV100656560; called by muse, mutect2, varscan2
- CCAR1 | c.3153A>G p.V1051= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs933920538, COSV99771489; called by muse, mutect2, varscan2
- CCDC198 | c.867C>T p.F289= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs146789384; called by muse, mutect2, varscan2
- CDK16 | c.117T>C p.G39= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs777199690, COSV99332022; called by muse, mutect2, varscan2
- CELSR1 | c.3483G>A p.Q1161= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV99420389; called by muse, mutect2, varscan2
- CHAT | c.1068C>T p.D356= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs748193892, COSV60320071; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLPTM1L | c.663C>T p.R221= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs369069044; called by muse, mutect2, varscan2
- CPSF1 | c.2379C>A p.T793= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1554864389, COSV100450774; called by muse, mutect2, varscan2
- DCTD | c.339C>T p.C113= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs750298019, COSV63866709; called by muse, mutect2, varscan2
- DFFB | c.360T>G p.A120= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100138812; called by muse, mutect2, varscan2
- DIP2A | c.222C>T p.A74= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100595746, COSV59476787; called by muse, mutect2, varscan2
- DUOX2 | c.2814G>A p.T938= | Silent (SNP) | VAF 26/47 reads (55%) | catalogued as rs749252728, COSV101199795; called by muse, mutect2, varscan2
- ELOA2 | c.636G>A p.Q212= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99798401; called by muse, mutect2
- EPM2AIP1 | c.156C>T p.R52= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs780820228, COSV99212832; called by muse, mutect2, varscan2
- FBLN1 | c.90T>C p.D30= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99411690; called by muse, mutect2
- FCER1A | c.547C>T p.L183= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV100929316, COSV63668773; called by muse, mutect2, varscan2
- FCGBP | c.6939C>T p.Y2313= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs574260833; called by muse, mutect2, varscan2
- FDCSP | c.249C>T p.S83= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs200937610, COSV58764470; called by muse, mutect2, varscan2
- FOXM1 | c.1584G>A p.S528= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs143720457; called by muse, mutect2, varscan2
- GAS8 | c.115C>A p.R39= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99244261; called by mutect2, varscan2
- GRM1 | c.1107T>A p.P369= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99269499; called by muse, mutect2, varscan2
- H1-5 | c.243C>T p.S81= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs1405147097, COSV100138115; called by muse, mutect2, varscan2
- HEXIM1 | c.273C>A p.G91= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100203623; called by muse, mutect2, varscan2
- HSPBP1 | c.495G>A p.A165= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs771040201, COSV99729330; called by muse, varscan2
- IGF2R | c.5799C>T p.Y1933= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs2230049; called by muse, mutect2, varscan2
- IGSF10 | c.1312C>T p.L438= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99198988; called by muse, mutect2, varscan2
- KIAA0408 | c.177T>C p.N59= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100847095; called by muse, mutect2
- KRT16 | c.636G>A p.L212= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100053068; called by muse, mutect2
- LAMTOR2 | c.294C>T p.T98= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs777537272, COSV63107781; called by muse, mutect2, varscan2
- LILRA6 | c.855T>C p.P285= | Silent (SNP) | VAF 35/220 reads (16%) | catalogued as rs1304727217, COSV99558683; called by muse, mutect2, varscan2
- LPAR2 | c.225C>T p.A75= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99179661; called by muse, mutect2, varscan2
- MMP9 | c.1377G>A p.P459= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs1053503107, COSV100812478; called by muse, mutect2
- MSN | c.801C>T p.F267= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV100814071, COSV64303986; called by muse, mutect2, varscan2
- NDST3 | c.1113T>C p.S371= | Silent (SNP) | VAF 91/217 reads (42%) | catalogued as COSV99632145; called by muse, mutect2, varscan2
- NF1 | c.5379A>T p.L1793= (on ENST00000358273 / NM_001042492.3; = p.L1772= on NM_000267.3) | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100648445; called by muse, mutect2, varscan2
- NOC3L | c.246A>G p.E82= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1484111564, COSV64929972; called by muse, mutect2
- NUFIP2 | c.648C>T p.S216= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs546326872, COSV56604004; called by muse, mutect2, varscan2
- OR10H5 | c.342G>A p.L114= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV100454825; called by muse, mutect2, varscan2
- OR14C36 | c.618C>T p.G206= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs767819229, COSV58602456; called by muse, mutect2, varscan2
- ORMDL3 | c.429C>T p.H143= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1484054815, COSV100401602; called by muse, mutect2, varscan2
- PARD3 | c.1809C>T p.V603= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100402194; called by muse, mutect2, varscan2
- PARP8 | c.2397G>T p.L799= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV55858302, COSV99893011; called by muse, mutect2
- PDLIM5 | c.609C>T p.V203= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100524460; called by muse, mutect2, varscan2
- PPP2R2A | c.1059T>C p.S353= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100277393; called by muse, mutect2, varscan2
- PREB | c.636C>A p.T212= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99574862; called by muse, mutect2, varscan2
- PSMC6 | c.603T>A p.V201= (on ENST00000612399; = p.V187= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV101471217; called by muse, mutect2, varscan2
- PTGDR2 | c.501C>T p.F167= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs777347417, COSV99920200; called by muse, mutect2, varscan2
- PTGES2 | c.408C>T p.R136= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs772837708, COSV99476492; called by muse, mutect2, varscan2
- PTGS2 | c.1284C>A p.P428= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100821860; called by muse, mutect2, varscan2
- RASA1 | c.402T>C p.F134= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs1329000012, COSV99171188; ClinVar: uncertain significance; called by mutect2, varscan2
- RBPJL | c.1230C>T p.H410= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1370051691, COSV100643556, COSV99056345; called by muse, mutect2, varscan2
- REEP2 | c.487C>T p.L163= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99649796; called by muse, mutect2, varscan2
- RTP5 | c.495C>T p.N165= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs761978952, COSV100574818; called by muse, mutect2, varscan2
- S100A7A | c.282G>A p.A94= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs201874755; called by muse, mutect2, varscan2
- SEMA3B | c.1683C>T p.D561= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV100312956; called by muse, mutect2, varscan2
- SIX6 | c.381C>T p.D127= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV59803428; called by muse, mutect2, varscan2
- SPAG17 | c.3399G>A p.S1133= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as rs370528649; called by muse, mutect2, varscan2
- SRRT | c.168G>A p.R56= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV100730411; called by muse, mutect2, varscan2
- ST14 | c.1425C>G p.A475= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV99599204; called by muse, varscan2
- TAAR8 | c.786G>A p.T262= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs367973626; called by muse, mutect2, varscan2
- TNPO2 | c.1284C>T p.G428= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs747015494, COSV100790431; called by muse, mutect2, varscan2
- TRPV5 | c.855C>T p.S285= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV54689349; called by muse, mutect2, varscan2
- TSPAN13 | c.129C>A p.L43= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV100018211; called by muse, mutect2, varscan2
- TTN | c.159C>T p.G53= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs1367693905, COSV60406020; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBN1 | c.273C>T p.F91= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs907716656, COSV52171421, COSV99278749; called by muse, mutect2, varscan2
- VPS13C | c.1429T>C p.L477= (on ENST00000644861 / NM_020821.3; = p.L434= on NM_017684.5) | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99830529; called by muse, mutect2, varscan2
- WIPI1 | c.1215G>A p.A405= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs537010882, COSV50930299; called by muse, mutect2, varscan2
- WSB1 | c.930T>C p.N310= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52216514; called by muse, mutect2, varscan2
- ZBTB25 | c.387T>C p.Y129= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV101170764; called by muse, mutect2, varscan2
- ZNF710 | c.609C>T p.S203= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99184294; called by muse, mutect2, varscan2
- ZNF778 | c.345G>A p.Q115= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV100124748; called by muse, mutect2, varscan2
- ZNF831 | c.867G>T p.G289= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs761196821, COSV100926309; called by muse, mutect2, varscan2
- ADRA1A | c.1270-8023_1270-8022del | Intron (DEL) | VAF 16/79 reads (20%) | called by pindel, varscan2
- CARMIL1 | c.614+1525_614+1526del | Intron (DEL) | VAF 30/35 reads (86%) | catalogued as rs747471059; called by mutect2, varscan2
- KALRN | c.4929+21992C>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as COSV99567694; called by muse, mutect2, varscan2
- MIR363 | n.6T>C | RNA (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-2470G>A | Intron (SNP) | VAF 24/121 reads (20%) | catalogued as rs539916563, COSV52780914, COSV99485306; called by muse, varscan2
- POM121C | chr7:75416080 C>T | 3'Flank (SNP) | VAF 22/48 reads (46%) | catalogued as rs587704911; called by muse, mutect2, varscan2
- SMIM12 | chr1:34855394 G>A | 3'Flank (SNP) | VAF 3/16 reads (19%) | catalogued as COSV101315047, COSV101315085; called by muse, mutect2
- UVSSA | c.*9125G>A | 3'UTR (SNP) | VAF 126/291 reads (43%) | catalogued as rs115168119; called by muse, mutect2, varscan2
